Somatic mutation profile of tumor specimen TCGA-CK-5913-01A (aliquot TCGA-CK-5913-01A-11D-1650-10) from TCGA case TCGA-CK-5913, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 58.6 years (21,399 days).
Specimen TCGA-CK-5913-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7edcd41-71b0-4a19-90b8-d179dec7ce6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CK-5913-10A (Blood Derived Normal), aliquot TCGA-CK-5913-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5496a95-9e9a-483c-a1c6-16b19bf86912

The open-access MAF lists 975 somatic variants for this specimen: 748 protein-altering or splice-affecting, 209 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 513, Silent 209, Frame Shift Del 139, Frame Shift Ins 40, Nonsense Mutation 29, Splice Region 11, Splice Site 9, In Frame Del 7, Intron 6, RNA 5, 5'Flank 3, 3'Flank 2.

Variants (750 of 975; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.219del p.R74Gfs*23 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as rs398123489; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AGXT | c.33del p.K12Rfs*34 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | catalogued as rs180177201, CM056286; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ARID1B | c.3970C>T p.R1324* | Nonsense Mutation (SNP) | VAF 60/158 reads (38%) | catalogued as rs773740590, CM1310769, COSV51676754; ClinVar: pathogenic; called by muse, varscan2
- B2M | c.68-2A>G p.X23_splice | Splice Site (SNP) | VAF 46/113 reads (41%) | hotspot (GDC flag); catalogued as rs111482205, COSV62562974, COSV62564351; called by muse, mutect2
- BRCA2 | c.4631del p.N1544Tfs*24 | Frame Shift Del (DEL) | VAF 28/151 reads (19%) | catalogued as rs80359460; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CLEC14A | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV60564301; called by muse, mutect2, varscan2
- DHTKD1 | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 34/113 reads (30%) | catalogued as rs770649540, COSV53806077; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ENG | c.1199del p.G400Vfs*21 | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | catalogued as rs1060501422, CD031045; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- IQSEC2 | c.2563C>T p.R855* (on ENST00000642864 / NM_001111125.3; = p.R650* on NM_015075.2) | Nonsense Mutation (SNP) | VAF 18/127 reads (14%) | catalogued as rs587777261, CM129316, COSV64724818; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MFRP | chr11:119345562 ins G | 5'Flank (INS) | VAF 17/45 reads (38%) | catalogued as rs587776596; ClinVar: pathogenic; called by mutect2, varscan2
- MYO7A | c.397del p.H133Tfs*13 | Frame Shift Del (DEL) | VAF 21/92 reads (23%) | catalogued as rs111033187; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- NPHP3 | c.406del p.T136Rfs*13 | Frame Shift Del (DEL) | VAF 146/472 reads (31%) | catalogued as rs1379989124, CD1211305; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 52/184 reads (28%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TRIP11 | c.1622del p.K541Rfs*17 | Frame Shift Del (DEL) | VAF 233/743 reads (31%) | catalogued as rs1420691965; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AATK | c.2891C>T p.A964V (on ENST00000326724 / NM_001080395.3; = p.A861V on NM_004920.2) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs773881001, COSV100353069; called by muse, mutect2, varscan2
- ABCA12 | c.6973C>A p.H2325N (on ENST00000272895 / NM_173076.3; = p.H2007N on NM_015657.3) | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV55955818, COSV55975923; called by muse, mutect2, varscan2
- ABCA2 | c.6521C>T p.T2174M (on ENST00000614293; = p.T2144M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV99688123; called by muse, mutect2, varscan2
- ABCB11 | c.3149G>A p.R1050H | Missense Mutation (SNP) | VAF 136/356 reads (38%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.912); catalogued as rs946572327, COSV55596705; called by muse, mutect2, varscan2
- ABCC12 | c.2805dup p.M936Yfs*84 | Frame Shift Ins (INS) | VAF 30/110 reads (27%) | catalogued as rs1353186335; called by mutect2, pindel, varscan2
- ABI3BP | c.2635A>G p.K879E | Missense Mutation (SNP) | VAF 120/692 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as COSV99427905; called by muse, varscan2
- ACBD4 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as COSV58853495; called by muse, mutect2, varscan2
- ACE | c.3446C>T p.T1149M | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.552); catalogued as rs764430271, COSV99327428; called by muse, mutect2, varscan2
- ACOT4 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100412892; called by muse, varscan2
- ACSL5 | c.788G>T p.G263V (on ENST00000354273; = p.G319V on NM_016234.3) | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61133539; called by muse, mutect2, varscan2
- ACSS1 | c.1777T>C p.F593L | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100053909; called by muse, varscan2
- ACSS1 | c.431G>T p.R144M | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV60225111; called by muse, mutect2, varscan2
- ACTR1B | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as rs565812380, COSV56703875; called by muse, mutect2, varscan2
- ADAM28 | c.1288A>G p.T430A | Missense Mutation (SNP) | VAF 126/1068 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs762484740, COSV56105568; called by muse, mutect2, varscan2
- ADAMTS10 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.537); catalogued as rs144419462; called by muse, mutect2, varscan2
- ADCY5 | c.3170G>A p.R1057Q | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs139641136; called by muse, mutect2, varscan2
- ADCY8 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs780136130, COSV53928091; called by muse, mutect2, varscan2
- ADGRB1 | c.948C>T p.P316= | Splice Region (SNP) | VAF 17/67 reads (25%) | catalogued as rs1194650343, COSV60103505; called by muse, mutect2, varscan2
- ADGRB2 | c.3616C>T p.R1206C | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs151028224; called by muse, mutect2, varscan2
- ADGRB3 | c.2308T>G p.L770V | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs755820853, COSV65408728; called by muse, mutect2
- ADH1B | c.1058T>C p.F353S | Missense Mutation (SNP) | VAF 94/338 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1407451886, COSV59298822; called by muse, mutect2, varscan2
- ADRB2 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 79/217 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100019278; called by muse, mutect2, varscan2
- AGTR1 | c.728T>C p.M243T | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV62560187; called by muse, mutect2, varscan2
- AHNAK2 | c.5294G>A p.G1765D | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs377659852; called by muse, mutect2, varscan2
- AK9 | c.3633+3A>G | Splice Region (SNP) | VAF 21/66 reads (32%) | catalogued as rs1246538327, COSV100394061; called by muse, mutect2, varscan2
- AKR1C1 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 52/399 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782138465, COSV101080530; called by muse, mutect2, varscan2
- ANGPT1 | c.1422A>G p.I474M | Missense Mutation (SNP) | VAF 198/752 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1226475969, COSV99863608; called by muse, varscan2
- ANGPTL7 | c.792G>C p.Q264H | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV63878373; called by muse, mutect2, varscan2
- ANK1 | c.1910C>T p.T637M | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs769870526, COSV55878317; called by muse, mutect2, varscan2
- ANKRD35 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs782145699, COSV62910724; called by muse, mutect2, varscan2
- AP1M1 | c.163del p.V55Sfs*182 | Frame Shift Del (DEL) | VAF 20/75 reads (27%) | catalogued as rs753324780, COSV52227333; called by mutect2, pindel, varscan2
- AP5S1 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs765677394, COSV55694684, COSV99853335; called by muse, mutect2, varscan2
- APCDD1 | c.773A>G p.K258R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV62373371; called by muse, mutect2, varscan2
- APLP1 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52880146; called by muse, mutect2, varscan2
- ARHGAP22 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV50963896, COSV50988110; called by muse, mutect2, varscan2
- ARHGAP30 | c.433C>A p.L145M | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63519408; called by muse, mutect2, varscan2
- ARHGAP32 | c.4934G>A p.R1645Q (on ENST00000310343 / NM_001378025.1; = p.R1296Q on NM_014715.4) | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758198053, COSV100088532; called by muse, mutect2, varscan2
- ARHGAP5 | c.2576G>A p.R859Q | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760626630, COSV61539322; called by muse, mutect2, varscan2
- ARHGEF11 | c.1471C>T p.R491* | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | catalogued as COSV63813973; called by muse, mutect2, varscan2
- ARID1A | c.1561C>T p.Q521* | Nonsense Mutation (SNP) | VAF 56/167 reads (34%) | catalogued as COSV61389265; called by muse, mutect2, varscan2
- ARMC4 | c.2380C>T p.R794W | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs35280610; called by muse, mutect2
- ARMCX6 | c.46A>T p.I16F | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62680964; called by muse, mutect2, varscan2
- ASPH | c.1552G>A p.G518R | Missense Mutation (SNP) | VAF 65/260 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as rs1055400004, COSV101064431, COSV65247644; called by muse, mutect2, varscan2
- ASTN1 | c.1940A>G p.H647R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99922537; called by muse, mutect2
- ATP13A4 | c.2963C>A p.A988E | Missense Mutation (SNP) | VAF 97/253 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV61327363; called by muse, mutect2, varscan2
- ATP6V1C1 | c.373A>T p.I125F | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV67778923; called by muse, mutect2, varscan2
- B2M | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs752758095, COSV62564872, COSV62565749, COSV62566315; called by muse, mutect2, varscan2
- B3GNT6 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62828372; called by muse, varscan2
- BAHCC1 | c.3446G>A p.G1149E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as rs782153531, COSV57033429; called by muse, mutect2, varscan2
- BANP | c.1114G>A p.A372T (on ENST00000286122; = p.A341T on NM_017869.4) | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); catalogued as rs757034546, COSV53740641; called by muse, mutect2, varscan2
- BCAT1 | c.293T>A p.L98* | Nonsense Mutation (SNP) | VAF 48/138 reads (35%) | catalogued as COSV53917824; called by muse, mutect2, varscan2
- BCKDHB | c.620G>A p.C207Y | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV57518844; called by muse, mutect2
- BCKDK | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as COSV54891121, COSV54894410; called by muse, mutect2, varscan2
- BCL11B | c.593G>A p.G198D | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.247); catalogued as COSV61739487; called by muse, mutect2, varscan2
- BCL6B | c.842C>A p.A281D | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.156); catalogued as COSV53430343; called by muse, mutect2, varscan2
- BDH2 | c.374C>A p.S125Y | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs142838082, COSV56479723; called by muse, varscan2
- BEX3 | c.211A>G p.M71V | Missense Mutation (SNP) | VAF 40/440 reads (9%) | SIFT tolerated (1); PolyPhen possibly damaging (0.621); catalogued as COSV55421814; called by muse, mutect2
- BFSP2 | c.448T>C p.W150R | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56592116; called by muse, mutect2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | catalogued as rs755506199; called by mutect2, varscan2
- BMP7 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.82); catalogued as rs766490422, COSV67780297; called by muse, mutect2, varscan2
- BPIFA3 | c.251G>T p.R84M | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV64926270; called by muse, mutect2, varscan2
- BPIFB6 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs762415914, COSV62756691; called by muse, mutect2, varscan2
- BPNT1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs1038226144, COSV100435760; called by muse, mutect2
- BSN | c.10282C>T p.R3428W | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751008096, COSV56527808; called by muse, mutect2, varscan2
- BSX | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1466704692, COSV58006322; called by muse, mutect2, varscan2
- BTN1A1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV55069655; called by muse, mutect2, varscan2
- C11orf16 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs1208938781, COSV58169117; called by muse, mutect2, varscan2
- C15orf39 | c.2752C>A p.R918S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV62296754, COSV62298266; called by muse, mutect2, varscan2
- C19orf54 | c.890A>G p.Y297C | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as rs1197687067, COSV99648959; called by muse, mutect2
- C1orf116 | c.1719dup p.C574Lfs*14 | Frame Shift Ins (INS) | VAF 12/53 reads (23%) | catalogued as rs780657010; called by mutect2, varscan2
- C1orf122 | c.268del p.Q90Sfs*42 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs747134922; called by mutect2, pindel
- C5 | c.4372G>T p.G1458* | Nonsense Mutation (SNP) | VAF 14/172 reads (8%) | catalogued as COSV56332201; called by muse, mutect2
- C6orf118 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs751263940, COSV57814454; called by muse, mutect2, varscan2
- C6orf118 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.255); catalogued as rs1375252947, COSV100025435, COSV57819576; called by muse, mutect2, varscan2
- CA9 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV65676543; called by muse, mutect2, varscan2
- CACNA1D | c.909dup p.A304Cfs*2 | Frame Shift Ins (INS) | VAF 57/237 reads (24%) | catalogued as rs1186715228; called by mutect2, varscan2
- CACNA1H | c.2140C>A p.L714I | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV100673244; called by muse, mutect2
- CALCOCO1 | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50424652; called by muse, mutect2, varscan2
- CALD1 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762365246, COSV62653752; called by muse, mutect2, varscan2
- CALU | c.31T>A p.S11T | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV50823525; called by muse, mutect2, varscan2
- CAMK2G | c.1559G>A p.G520E (on ENST00000423381 / NM_001367518.1; = p.G457E on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.35); catalogued as COSV55217988; called by muse, mutect2, varscan2
- CARMIL2 | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV100576168; called by muse, mutect2
- CARS1 | c.587A>G p.D196G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.515); catalogued as COSV53451747; called by mutect2, varscan2
- CBLN3 | c.206del p.P69Lfs*35 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | catalogued as rs1268177561; called by mutect2, pindel
- CCDC120 | c.1390del p.E464Sfs*170 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as COSV64481542; called by mutect2, varscan2
- CCDC148 | c.497T>C p.V166A | Missense Mutation (SNP) | VAF 109/340 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV51770842; called by muse, mutect2, varscan2
- CCDC24 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762726501, COSV62210088; called by muse, mutect2, varscan2
- CCDC42 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1044515346, COSV53449885; called by muse, mutect2, varscan2
- CCDC66 | c.619dup p.T207Nfs*2 (on ENST00000394672 / NM_001353147.1; = p.T173Nfs*2 on NM_001012506.5 and 6 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 73/255 reads (29%) | catalogued as rs1247408644; called by mutect2, varscan2
- CCDC9B | c.294del p.M99Wfs*3 | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | catalogued as rs765438623; called by mutect2, pindel, varscan2
- CCR7 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs759676455, COSV55849835; called by muse, mutect2, varscan2
- CD163 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs748750295, COSV63133563; called by muse, mutect2
- CD276 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs762931731, COSV59205760; called by muse, mutect2, varscan2
- CD99L2 | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 304/601 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); catalogued as COSV60938543; called by muse, mutect2, varscan2
- CDC25A | c.1336A>T p.R446* | Nonsense Mutation (SNP) | VAF 36/123 reads (29%) | catalogued as COSV56769745; called by muse, mutect2, varscan2
- CDCP2 | c.613del p.V205Cfs*106 | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | catalogued as COSV61286090; called by mutect2, pindel, varscan2
- CDK16 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs768402965, COSV52093962; called by muse, mutect2, varscan2
- CELSR3 | c.8473G>A p.A2825T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.033); catalogued as rs752951161, COSV51153466; called by muse, mutect2, varscan2
- CEP290 | c.3700T>C p.Y1234H | Missense Mutation (SNP) | VAF 41/395 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV58348877, COSV58356435; called by muse, mutect2, varscan2
- CES3 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs960577194, COSV57595489; called by muse, mutect2, varscan2
- CFAP47 | c.5141C>A p.S1714Y | Missense Mutation (SNP) | VAF 134/1327 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV57976674; called by muse, mutect2, varscan2
- CFAP65 | c.1695C>A p.S565R | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as COSV100445554; called by muse, mutect2, varscan2
- CH25H | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs1273528809, COSV64092563; called by muse, mutect2, varscan2
- CHRM2 | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV57784952; called by muse, mutect2, varscan2
- CHRNA4 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs201575409, COSV100937273, COSV100937286; called by muse, mutect2, varscan2
- CHRNE | c.769C>A p.L257M | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.47); PolyPhen probably damaging (1); catalogued as COSV99545171; called by muse, mutect2, varscan2
- CIC | c.2699-1G>A p.X900_splice | Splice Site (SNP) | VAF 70/260 reads (27%) | catalogued as COSV50554516; called by muse, mutect2, varscan2
- CKAP2L | c.811G>T p.G271* | Nonsense Mutation (SNP) | VAF 81/371 reads (22%) | catalogued as COSV56698304; called by muse, mutect2, varscan2
- CLCA2 | c.391G>T p.G131W | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100991630; called by muse, mutect2
- CLDN12 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV55308050; called by muse, mutect2
- CLIC4 | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 88/228 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV65527707; called by muse, mutect2, varscan2
- CLIP1 | c.1738C>T p.R580W (on ENST00000620786 / NM_001247997.1; = p.R569W on NM_002956.2) | Missense Mutation (SNP) | VAF 91/266 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs767835144, COSV56808731; called by muse, mutect2, varscan2
- CLTA | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as rs10972787, COSV54255901; called by muse, mutect2, varscan2
- CMYA5 | c.7349C>A p.S2450Y | Missense Mutation (SNP) | VAF 28/337 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs772792477, COSV71404556, COSV71409545; called by muse, mutect2
- CNOT1 | c.2915G>A p.C972Y | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55322377; called by muse, mutect2, varscan2
- CNRIP1 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748240304, COSV55150226; called by muse, mutect2, varscan2
- COL17A1 | c.3958T>C p.S1320P | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV59829190; called by muse, mutect2, varscan2
- COL4A6 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 116/229 reads (51%) | catalogued as COSV57878447; called by muse, mutect2, varscan2
- COL5A1 | c.655-1G>T p.X219_splice | Splice Site (SNP) | VAF 71/187 reads (38%) | catalogued as COSV65664823, COSV65673937; called by muse, mutect2, varscan2
- COL7A1 | c.6893del p.P2298Lfs*90 | Frame Shift Del (DEL) | VAF 19/115 reads (17%) | catalogued as CD072371; called by mutect2, pindel, varscan2
- CORO1C | c.149T>C p.I50T | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.652); catalogued as COSV54599065; called by muse, mutect2, varscan2
- CRACDL | c.2431C>T p.P811S | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV67410195; called by muse, mutect2, varscan2
- CRB1 | c.2984A>T p.E995V | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV66333910; called by muse, mutect2, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 34/98 reads (35%) | catalogued as rs747437399; called by mutect2, pindel, varscan2
- CSNK1G3 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62057012; called by muse, mutect2, varscan2
- CSTF2 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.15); catalogued as COSV65895203; called by muse, mutect2, varscan2
- CUL9 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV52734852; called by muse, mutect2, varscan2
- CXCL5 | c.17G>T p.S6I | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV56019201, COSV99932920; called by muse, mutect2, varscan2
- CYGB | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as COSV53151430; called by muse, mutect2, varscan2
- CYP8B1 | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.296); catalogued as COSV60227693; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | catalogued as rs751187768; called by mutect2, varscan2
- DACH1 | c.2261C>T p.T754I (on ENST00000619232 / NM_001366712.1; = p.T500I on NM_004392.6) | Missense Mutation (SNP) | VAF 98/290 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV57520014; called by muse, mutect2, varscan2
- DAO | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373913310, COSV57321201; called by muse, mutect2, varscan2
- DBX1 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV57054749; called by muse, varscan2
- DCAF12L1 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV64421432; called by muse, mutect2, varscan2
- DCAF12L1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV100948383; called by muse, mutect2, varscan2
- DCAF12L2 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100758730; called by muse, mutect2, varscan2
- DCTN2 | c.665C>T p.A222V (on ENST00000548249 / NM_001261413.2; = p.A227V on NM_006400.4) | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); catalogued as rs1196416688, COSV63076445; called by muse, mutect2, varscan2
- DDX1 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 106/288 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV51843532; called by muse, mutect2, varscan2
- DGAT2L6 | c.415G>T p.G139W | Missense Mutation (SNP) | VAF 98/668 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV60718786; called by muse, mutect2, varscan2
- DGCR2 | c.1042A>G p.M348V | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99593843; called by muse, mutect2, varscan2
- DGKI | c.829C>A p.H277N | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV55976546; called by muse, mutect2, varscan2
- DGKK | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 88/360 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.25); catalogued as COSV101053008; called by muse, varscan2
- DHH | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750409317, COSV57202979; called by muse, mutect2, varscan2
- DIDO1 | c.6451C>T p.R2151W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs769371080, COSV56634093, COSV99825187; called by muse, mutect2, varscan2
- DLG5 | c.4046G>A p.R1349H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762391739, COSV64946751; called by muse, mutect2, varscan2
- DMAC1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64066109; called by muse, mutect2, varscan2
- DNAH5 | c.5551T>C p.F1851L | Missense Mutation (SNP) | VAF 59/388 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99452173; called by muse, mutect2, varscan2
- DNAJC18 | c.80A>G p.D27G | Missense Mutation (SNP) | VAF 114/316 reads (36%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV57416850; called by muse, mutect2, varscan2
- DNM3 | c.2168A>G p.Q723R (on ENST00000355305 / NM_001350206.2; = p.Q717R on NM_015569.5) | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.596); catalogued as COSV62467504; called by muse, mutect2
- DNMT1 | c.4721G>A p.R1574Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61583931; called by muse, mutect2, varscan2
- DNMT1 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.142); catalogued as rs775360871, COSV61583945; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 54/162 reads (33%) | catalogued as rs782552436; called by mutect2, varscan2
- DOCK6 | c.4580G>A p.R1527H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs745393166, COSV53922646; called by muse, mutect2, varscan2
- DPYD | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs943095330, COSV64614996; called by muse, mutect2, varscan2
- DPYSL5 | c.1571G>A p.G524D | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV56516362; called by muse, mutect2, varscan2
- DRC1 | c.1851del p.W618Gfs*19 | Frame Shift Del (DEL) | VAF 44/152 reads (29%) | catalogued as rs781097632, COSV55514089; called by mutect2, pindel, varscan2
- DRGX | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs568384275, COSV65137618; called by muse, mutect2, varscan2
- DRP2 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1321997185, COSV65809574; called by muse, mutect2, varscan2
- DSP | c.3590A>G p.N1197S | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV65794681, COSV65796132; called by muse, mutect2, varscan2
- DUOX1 | c.4537C>T p.R1513W | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as rs756591126, COSV52052741; called by muse, mutect2, varscan2
- DUOX2 | c.3646C>T p.R1216W | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs144886975; called by muse, mutect2, varscan2
- DUSP15 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs771404423, COSV54066380; called by muse, mutect2, varscan2
- ECE1 | c.1970A>G p.E657G | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV99942126; called by muse, mutect2, varscan2
- ECT2 | c.421C>A p.L141I (on ENST00000392692 / NM_001349098.2; = p.L110I on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/354 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.816); catalogued as COSV51694246; called by muse, mutect2
- EFCAB13 | c.1151A>G p.Y384C | Missense Mutation (SNP) | VAF 110/266 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs373076606; called by muse, mutect2, varscan2
- EGFR | c.561C>T p.C187= | Splice Region (SNP) | VAF 52/139 reads (37%) | catalogued as rs776568205, COSV51848028; called by muse, mutect2, varscan2
- EHHADH | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs753038564, COSV51631826; called by muse, mutect2, varscan2
- EIF4G3 | c.421del p.T141Lfs*2 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | catalogued as rs1290746509; called by mutect2, pindel, varscan2
- EMD | c.610C>A p.R204S | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as rs782299893, COSV63962512; called by muse, mutect2, varscan2
- EMILIN3 | c.1981C>T p.L661F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV60038815; called by muse, mutect2, varscan2
- EML5 | c.4624C>A p.L1542M (on ENST00000380664; = p.L1550M on NM_183387.3) | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100715991; called by muse, varscan2
- EP300 | c.3416A>G p.Y1139C | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54345907; called by muse, mutect2, varscan2
- EP400 | c.5216G>A p.C1739Y | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV57786650; called by muse, mutect2, varscan2
- EPAS1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 101/277 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55390479; called by muse, mutect2, varscan2
- EPC2 | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 78/214 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs760629662, COSV51549607; called by muse, varscan2
- EPHA3 | c.696C>A p.N232K | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.968); catalogued as COSV60727792; called by muse, mutect2, varscan2
- ERC2 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 115/337 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs780658083, COSV55664639; called by muse, mutect2, varscan2
- ERICH3 | c.3865G>A p.A1289T | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.196); catalogued as COSV58618705; called by muse, mutect2, varscan2
- ESYT1 | c.2416C>T p.R806W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs762719993, COSV57271529; called by muse, mutect2, varscan2
- EXOSC10 | c.2582C>T p.S861L (on ENST00000376936 / NM_001001998.3; = p.S836L on NM_002685.4) | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs777173257, COSV58668146; called by muse, mutect2, varscan2
- EXTL3 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs748989305, COSV55040506; called by muse, mutect2, varscan2
- FAM193A | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs151258029, COSV61198749; called by muse, mutect2, varscan2
- FAM193B | c.2258G>A p.R753Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs144161370, COSV61558105; called by muse, mutect2, varscan2
- FAM227B | c.1237A>T p.T413S | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as COSV100175384; called by muse, mutect2, varscan2
- FAM47C | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs199727942, COSV63723857; called by muse, mutect2, varscan2
- FAM78B | c.616G>T p.G206W | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV57982493; called by muse, mutect2, varscan2
- FAM86B1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs764844308, COSV100392373; called by muse, mutect2, varscan2
- FAM9B | c.532dup p.S178Ffs*3 | Frame Shift Ins (INS) | VAF 252/1152 reads (22%) | catalogued as rs752791732; called by mutect2, pindel, varscan2
- FASN | c.1236del p.A413Hfs*39 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | catalogued as COSV60760319; called by mutect2, varscan2
- FAT2 | c.8777C>T p.A2926V | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs377736336; called by muse, mutect2, varscan2
- FAT4 | c.860A>G p.Y287C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67900489; called by muse, mutect2, varscan2
- FBN1 | c.4184A>G p.Y1395C | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV57330728; called by muse, mutect2, varscan2
- FBN1 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs1305871580, COSV100355940; called by muse, mutect2, varscan2
- FBXL13 | c.1771T>C p.S591P | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV57544636; called by muse, mutect2, varscan2
- FBXO10 | c.2392G>T p.G798C | Missense Mutation (SNP) | VAF 87/247 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52835702; called by muse, mutect2, varscan2
- FBXO41 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1248257745, COSV54584821; called by muse, mutect2, varscan2
- FCGBP | c.3212C>T p.P1071L | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as rs1351812008; called by muse, mutect2, varscan2
- FCN1 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs761901711, COSV65662223; called by muse, mutect2, varscan2
- FEZF1 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.224); catalogued as COSV58659722; called by muse, mutect2, varscan2
- FGD1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV64309689; called by muse, mutect2, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 72/220 reads (33%) | catalogued as rs752076602; called by mutect2, varscan2
- FLG2 | c.2350G>T p.G784C | Missense Mutation (SNP) | VAF 97/298 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV66173485; called by muse, mutect2, varscan2
- FLRT2 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 35/92 reads (38%) | catalogued as rs1224442998, COSV58150419; called by muse, mutect2, varscan2
- FMO1 | c.1415A>G p.Q472R | Missense Mutation (SNP) | VAF 60/330 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV61447882; called by muse, mutect2, varscan2
- FN1 | c.2957G>A p.S986N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100117738; called by muse, mutect2
- FOSB | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.978); catalogued as rs763363699, COSV62278751; called by muse, varscan2
- FOSB | c.964G>A p.G322S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs767173866, COSV62279289; called by muse, mutect2, varscan2
- FOXD4L1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52076607; called by mutect2, varscan2
- FOXS1 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs377266974; called by muse, mutect2, varscan2
- FPGS | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1213991555, COSV100785186, COSV61229010; called by muse, mutect2, varscan2
- FSD1 | c.879G>T p.M293I | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV55698967; called by muse, mutect2, varscan2
- GABBR2 | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52295970; called by muse, mutect2, varscan2
- GABRA4 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 128/389 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as COSV99974393; called by muse, varscan2
- GAK | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1416256557, COSV58509804; called by muse, mutect2, varscan2
- GALNTL6 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 61/184 reads (33%) | catalogued as rs747462866, COSV101487752, COSV71831880; called by muse, mutect2, varscan2
- GART | c.144C>T p.T48= | Splice Region (SNP) | VAF 64/160 reads (40%) | catalogued as rs141635320, COSV51670813; called by muse, mutect2, varscan2
- GEMIN5 | c.2176del p.S726Vfs*24 | Frame Shift Del (DEL) | VAF 178/474 reads (38%) | catalogued as COSV53564949; called by mutect2, varscan2
- GIMAP6 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs376322381; called by muse, mutect2, varscan2
- GJA9 | c.10T>C p.W4R | Missense Mutation (SNP) | VAF 102/305 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs755330574, COSV62532833; called by muse, mutect2, varscan2
- GLE1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 83/247 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV99047415; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 52/134 reads (39%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GNB1L | c.500G>A p.C167Y | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61550007; called by muse, mutect2, varscan2
- GP6 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344152418, COSV59979720; called by muse, mutect2, varscan2
- GPR132 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0.173); catalogued as rs200040782; called by muse, mutect2, varscan2
- GPR31 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.497); catalogued as rs777956303, COSV64762039; called by muse, mutect2, varscan2
- GPR6 | c.325G>A p.V109M | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.59); catalogued as COSV51573689; called by muse, mutect2, varscan2
- GPX7 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV63652927; called by muse, mutect2, varscan2
- GRIN2C | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs778738879, COSV53118034; called by muse, mutect2, varscan2
- GRM1 | c.2455G>T p.V819L | Missense Mutation (SNP) | VAF 102/270 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51337776; called by muse, mutect2, varscan2
- GRM5 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 102/287 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs781430828, COSV59630466; called by muse, mutect2, varscan2
- GRM7 | c.2471C>T p.T824M | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs760785925, COSV100735969, COSV63169543; called by muse, mutect2, varscan2
- GSDMA | c.1238G>T p.R413I | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV52859759; called by muse, mutect2, varscan2
- GSE1 | c.3519G>A p.A1173= | Splice Region (SNP) | VAF 16/76 reads (21%) | catalogued as rs544100517, COSV99496496; called by muse, mutect2, varscan2
- GSG1 | c.551T>A p.L184Q (on ENST00000651961 / NM_001080555.4; = p.A189= on NM_031289.5) | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52197608; called by muse, mutect2, varscan2
- GTPBP8 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.517); catalogued as rs1345489429, COSV55607582; called by muse, varscan2
- GUCY2F | c.257A>G p.D86G | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99485389; called by muse, mutect2, varscan2
- HARBI1 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 84/217 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.31); catalogued as COSV56322163; called by muse, mutect2, varscan2
- HDX | c.1568T>C p.L523P | Missense Mutation (SNP) | VAF 380/773 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.347); catalogued as COSV52982960; called by muse, mutect2, varscan2
- HEATR1 | c.5275A>G p.S1759G | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100857729; called by muse, mutect2
- HERC1 | c.13153dup p.Q4385Pfs*25 | Frame Shift Ins (INS) | VAF 12/53 reads (23%) | catalogued as rs772789325; called by mutect2, varscan2
- HERC2 | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55326230; called by muse, mutect2, varscan2
- HEXD | c.1118G>A p.S373N (on ENST00000327949 / NM_001369487.1; = p.A403T on NM_173620.3) | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.057); catalogued as COSV60066174; called by muse, mutect2, varscan2
- HFM1 | c.2194C>A p.P732T | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54025957, COSV54037589; called by muse, mutect2, varscan2
- HHIP | c.1740C>A p.Y580* | Nonsense Mutation (SNP) | VAF 123/364 reads (34%) | catalogued as COSV56844287; called by muse, mutect2, varscan2
- HIPK3 | c.1066_1069del p.C356Qfs*24 | Frame Shift Del (DEL) | VAF 82/264 reads (31%) | catalogued as rs1471936667; called by pindel, varscan2
- HKDC1 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.074); catalogued as rs746771373, COSV100664711, COSV63579436; called by muse, mutect2, varscan2
- HLA-A | c.627del p.K210Rfs*4 | Frame Shift Del (DEL) | VAF 77/252 reads (31%) | catalogued as rs199474609; called by mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs767148651; called by mutect2, varscan2
- HSPA13 | c.1071T>A p.S357R | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53466500; called by muse, mutect2, varscan2
- HSPBAP1 | c.1056G>T p.E352D | Missense Mutation (SNP) | VAF 97/282 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV60243882; called by muse, mutect2, varscan2
- HSPG2 | c.4199C>T p.P1400L | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374895557; called by muse, mutect2, varscan2
- HTR5A | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 68/207 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs372189121, COSV55285281, COSV99839526; called by muse, mutect2, varscan2
- IBTK | c.477C>A p.S159R | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.691); catalogued as COSV60396280; called by muse, mutect2, varscan2
- IDI2 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs368608756, COSV52987696; called by muse, mutect2, varscan2
- IDS | c.709-1G>T p.X237_splice | Splice Site (SNP) | VAF 22/75 reads (29%) | catalogued as COSV61714724; called by muse, mutect2, varscan2
- IGSF1 | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 96/335 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100812202; called by muse, mutect2, varscan2
- IGSF5 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs117910095; called by muse, mutect2, varscan2
- IL12RB1 | c.710del p.P237Hfs*5 | Frame Shift Del (DEL) | VAF 39/147 reads (27%) | catalogued as CD123470; called by mutect2, pindel, varscan2
- IL17REL | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.364); catalogued as rs200521763; called by muse, mutect2, varscan2
- IL3RA | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 92/263 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs573840129, COSV58433363; called by muse, mutect2, varscan2
- IL6 | c.230T>C p.M77T | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.238); catalogued as rs775325818, COSV51734278; called by muse, mutect2
- IL6ST | c.1587del p.V530* | Frame Shift Del (DEL) | VAF 149/468 reads (32%) | catalogued as rs776023104; called by mutect2, pindel, varscan2
- INPP5J | c.1642G>A p.A548T (on ENST00000331075 / NM_001284285.2; = p.A180T on NM_001002837.2) | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.077); catalogued as COSV58515403; called by muse, mutect2, varscan2
- INTS6L | c.359dup p.L120Ffs*37 | Frame Shift Ins (INS) | VAF 207/1002 reads (21%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IPO13 | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100961288; called by muse, mutect2, varscan2
- IPO5 | c.269A>C p.K90T | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV55159988; called by muse, mutect2
- IQCA1 | c.2096T>A p.I699N | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54512968; called by muse, mutect2, varscan2
- IQGAP3 | c.2507C>T p.A836V | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV63254724; called by muse, mutect2, varscan2
- IRF2 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1447797564, COSV66929557; called by muse, mutect2, varscan2
- IRX1 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100116394; called by muse, mutect2, varscan2
- ISL1 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as COSV57935770; called by muse, mutect2, varscan2
- ITGA4 | c.1771C>T p.R591* | Nonsense Mutation (SNP) | VAF 76/196 reads (39%) | catalogued as rs753898074, COSV51998234; called by muse, mutect2, varscan2
- ITGB4 | c.512T>C p.F171S | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1384877197, COSV52332901; called by muse, mutect2, varscan2
- ITIH2 | c.1915A>G p.M639V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.471); catalogued as COSV100623348; called by muse, mutect2
- ITIH3 | c.1904T>C p.L635P | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV101407037; called by muse, mutect2
- JRK | c.1280_1282del p.S427del | In Frame Del (DEL) | VAF 28/145 reads (19%) | catalogued as rs1268243467; called by pindel, varscan2
- JRK | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70630515; called by muse, mutect2, varscan2
- KANSL1 | c.1969C>T p.R657C | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs766750754; called by muse, mutect2
- KBTBD8 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV55131577; called by muse, mutect2, varscan2
- KCNH3 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1199620983, COSV57793002; called by muse, mutect2, varscan2
- KCNH4 | c.920C>T p.T307I | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99237070, COSV99237647; called by muse, mutect2
- KCNH4 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs373776454, COSV99236780; called by muse, mutect2, varscan2
- KCTD2 | c.349G>T p.G117* | Nonsense Mutation (SNP) | VAF 34/120 reads (28%) | catalogued as COSV56903472; called by muse, mutect2, varscan2
- KDM2B | c.3146G>T p.S1049I | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV65645253; called by muse, mutect2, varscan2
- KDM5A | c.692G>A p.S231N | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV66996453; called by muse, mutect2, varscan2
- KHDRBS3 | c.140A>T p.D47V | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100878898; called by muse, mutect2, varscan2
- KIAA1549 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs776144844, COSV54328687, COSV54331145; called by muse, varscan2
- KIF16B | c.2341C>T p.R781C | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.308); catalogued as rs142424331; called by muse, mutect2, varscan2
- KIF26A | c.3880G>A p.A1294T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as rs991110513, COSV100181404; called by muse, mutect2, varscan2
- KLHDC7B | c.1622T>C p.I541T (on ENST00000395676; = p.I1182T on NM_138433.5) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67465266; called by muse, mutect2, varscan2
- KLHL20 | c.1013A>G p.Y338C | Missense Mutation (SNP) | VAF 146/412 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV52945110; called by muse, mutect2, varscan2
- KLHL34 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV65280286; called by muse, mutect2, varscan2
- KLHL36 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.566); catalogued as COSV50724181; called by muse, mutect2, varscan2
- KLRC2 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 792/3320 reads (24%) | catalogued as COSV67900656; called by muse, varscan2
- KMT2A | c.8818A>G p.T2940A | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.031); catalogued as COSV63292605; called by muse, mutect2, varscan2
- KMT2B | c.4762G>A p.G1588R | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1228449559, COSV55862865; called by muse, mutect2, varscan2
- KSR2 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs747234277, COSV56669632; called by muse, mutect2, varscan2
- LAMA4 | c.1634G>A p.R545H (on ENST00000230538 / NM_001105206.3; = p.R538H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs143937452, COSV57905298; called by muse, mutect2, varscan2
- LARGE1 | c.1885G>A p.V629I | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.85); catalogued as rs547202997; called by muse, mutect2, varscan2
- LARP4 | c.1118del p.N373Ifs*3 | Frame Shift Del (DEL) | VAF 33/146 reads (23%) | catalogued as rs1179425728; called by mutect2, pindel, varscan2
- LBP | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs374549700, COSV54139002; called by muse, mutect2, varscan2
- LHX9 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV100435990; called by muse, mutect2, varscan2
- LIMK1 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as rs781956388, COSV60281124; called by muse, mutect2, varscan2
- LIPH | c.424G>T p.G142* | Nonsense Mutation (SNP) | VAF 72/183 reads (39%) | catalogued as COSV56186330; called by muse, mutect2, varscan2
- LIPT1 | c.395T>C p.L132S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60740467; called by muse, mutect2, varscan2
- LMBRD1 | c.971G>A p.R324H (on ENST00000649011; = p.R302H on NM_018368.4) | Missense Mutation (SNP) | VAF 84/235 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142962811; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LNX1 | c.1711C>T p.R571W (on ENST00000263925 / NM_001126328.3; = p.R475W on NM_032622.2) | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55791825; called by muse, mutect2, varscan2
- LOX | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs566461481, COSV50236931; called by muse, mutect2, varscan2
- LPA | c.4709G>A p.R1570K | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.93); catalogued as COSV100307235, COSV60312676; called by muse, mutect2, varscan2
- LRFN3 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs756974447, COSV55819133; called by muse, mutect2, varscan2
- LRIT1 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1334699433, COSV64513573; called by muse, mutect2, varscan2
- LRRIQ1 | c.1470del p.K490Nfs*28 | Frame Shift Del (DEL) | VAF 53/192 reads (28%) | catalogued as COSV101280733; called by mutect2, pindel, varscan2
- LRRK2 | c.6191A>G p.Y2064C | Missense Mutation (SNP) | VAF 97/267 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1159812449, COSV54171064; called by muse, mutect2, varscan2
- LRTM1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1032519205, COSV55515778; called by muse, mutect2, varscan2
- LSG1 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.277); catalogued as rs148904734; called by muse, mutect2, varscan2
- LTBP2 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs555894027, COSV100000729; called by muse, mutect2, varscan2
- LUC7L | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs764753668, COSV53457069; called by muse, mutect2, varscan2
- MAGEB6B | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1456844558; called by muse, mutect2, varscan2
- MAGEC1 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 99/380 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.448); catalogued as COSV53567323, COSV99596136; called by muse, mutect2, varscan2
- MAGIX | c.958del p.A320Qfs*? | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as COSV66256596; called by mutect2, pindel, varscan2
- MAP3K7 | c.1754A>G p.Y585C (on ENST00000369329 / NM_145331.3; = p.Y558C on NM_003188.4) | Missense Mutation (SNP) | VAF 221/679 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV65225468; called by muse, mutect2, varscan2
- MAP7D1 | c.2274G>T p.K758N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); catalogued as COSV60218554; called by muse, mutect2, varscan2
- MAP9 | c.1201G>A p.G401R | Missense Mutation (SNP) | VAF 167/475 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772352395, COSV60906554; called by muse, mutect2, varscan2
- MAPK15 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs201487703, COSV62030264; called by muse, mutect2, varscan2
- MARK4 | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs778118260, COSV53468990; called by muse, mutect2, varscan2
- MARVELD2 | c.1571A>G p.E524G | Missense Mutation (SNP) | VAF 96/581 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756327348, COSV57780447; called by mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 43/117 reads (37%) | catalogued as rs749738168; called by mutect2, pindel, varscan2
- MCM5 | c.475T>G p.S159A | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV53348294; called by muse, mutect2
- MDGA1 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); catalogued as COSV51801910; called by muse, varscan2
- MED13L | c.4573A>G p.I1525V | Missense Mutation (SNP) | VAF 39/432 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56118092; called by muse, mutect2
- MED14 | c.4037C>T p.A1346V | Missense Mutation (SNP) | VAF 135/478 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV61356152; called by muse, mutect2, varscan2
- MEFV | c.1995G>A p.W665* | Nonsense Mutation (SNP) | VAF 30/102 reads (29%) | catalogued as COSV54827745; called by muse, mutect2, varscan2
- MGA | c.7474C>T p.R2492W (on ENST00000219905 / NM_001164273.1; = p.R2283W on NM_001080541.2) | Missense Mutation (SNP) | VAF 97/250 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1411818407, COSV54963139; called by muse, mutect2, varscan2
- MIPEP | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs749656281, COSV66300848; called by muse, mutect2, varscan2
- MITF | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV100106155; called by muse, mutect2, varscan2
- MKX | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.075); catalogued as rs375241909, COSV65393331; called by muse, mutect2, varscan2
- MLXIPL | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1403010158, COSV57668094; called by muse, mutect2, varscan2
- MON2 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.208); catalogued as COSV54815262; called by muse, mutect2, varscan2
- MSN | c.536A>T p.H179L | Missense Mutation (SNP) | VAF 46/633 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100814269, COSV64305704; called by muse, mutect2
- MST1R | c.2264del p.G755Vfs*19 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs1407832113; called by mutect2, pindel, varscan2
- MT1E | c.88A>G p.K30E | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV57841980; called by muse, mutect2
- MTHFSD | c.308C>T p.P103L (on ENST00000360900 / NM_001159377.2; = p.P102L on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/257 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV59804803; called by muse, mutect2, varscan2
- MTX1 | c.22del p.R8Afs*110 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs755845788, COSV57426587; called by mutect2, pindel, varscan2
- MUC4 | c.14043C>T p.P4681= (on ENST00000463781 / NM_018406.7; = p.P445= on NM_004532.6) | Splice Region (SNP) | VAF 34/85 reads (40%) | catalogued as rs369959021, COSV57803466; called by muse, mutect2, varscan2
- MUC5B | c.3688G>A p.V1230I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.03); catalogued as rs372662304; called by muse, mutect2, varscan2
- MYBL2 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs1447840943, COSV53833756; called by muse, mutect2, varscan2
- MYL10 | c.534C>T p.V178= | Splice Region (SNP) | VAF 35/135 reads (26%) | catalogued as COSV56209155; called by muse, mutect2, varscan2
- MYO15A | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); catalogued as rs761641817, COSV52766362; called by muse, mutect2, varscan2
- NAXD | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs371200101, COSV57288528; called by muse, varscan2
- NAXD | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs371227030, COSV57289152; called by muse, varscan2
- NBEAL2 | c.3551G>A p.R1184H | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.151); catalogued as rs1292307405, COSV52755263; called by muse, mutect2, varscan2
- NBR1 | c.2236del p.L746Wfs*50 | Frame Shift Del (DEL) | VAF 24/118 reads (20%) | catalogued as rs34660735; called by mutect2, pindel
- NCOR1 | c.6446C>A p.P2149H | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV51996478; called by muse, mutect2, varscan2
- NDUFA10 | c.604del p.H202Tfs*3 | Frame Shift Del (DEL) | VAF 34/130 reads (26%) | catalogued as rs746019378; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NEFH | c.2110T>C p.S704P | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as COSV60215078; called by muse, mutect2, varscan2
- NEFM | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs372595703; called by muse, mutect2, varscan2
- NEMP1 | c.854A>G p.Q285R (on ENST00000300128 / NM_001130963.2; = p.Q212R on NM_015257.3) | Missense Mutation (SNP) | VAF 84/243 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV55664725; called by muse, mutect2
- NFE2L3 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.735); catalogued as rs566561270, COSV50228075; called by muse, mutect2, varscan2
- NFRKB | c.932del p.K311Rfs*13 (on ENST00000446488 / NM_001143835.2; = p.K336Rfs*13 on NM_006165.3) | Frame Shift Del (DEL) | VAF 40/107 reads (37%) | catalogued as rs149369172, COSV58756820; called by mutect2, varscan2
- NOS1 | c.2027del p.G676Afs*64 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | catalogued as rs746543323; called by mutect2, pindel, varscan2
- NOTCH3 | c.5404dup p.A1802Gfs*8 | Frame Shift Ins (INS) | VAF 22/62 reads (35%) | catalogued as rs753725730; called by mutect2, varscan2
- NR2E1 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 102/301 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1472108317, COSV64561768; called by muse, mutect2, varscan2
- NR5A2 | c.66T>C p.G22= | Splice Region (SNP) | VAF 22/106 reads (21%) | catalogued as COSV99371428; called by muse, mutect2, varscan2
- NRSN2 | c.547T>C p.F183L | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1300182766, COSV101206806; called by muse, mutect2, varscan2
- NTNG2 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62368769; called by muse, varscan2
- NUP155 | c.1474C>T p.Q492* (on ENST00000231498 / NM_153485.3; = p.Q433* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 58/166 reads (35%) | catalogued as COSV99193961; called by muse, mutect2, varscan2
- NUTM2F | c.2140C>A p.P714T | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as COSV99480267; called by mutect2, varscan2
- OBSCN | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); catalogued as COSV52770973; called by muse, mutect2, varscan2
- ODF3L2 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747742338, COSV52749556; called by muse, mutect2, varscan2
- OLFML3 | c.795del p.Y266Tfs*3 | Frame Shift Del (DEL) | VAF 29/75 reads (39%) | catalogued as rs753594963; called by mutect2, pindel, varscan2
- OPA3 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV54400648; called by muse, varscan2
- OR1Q1 | c.338T>C p.F113S | Missense Mutation (SNP) | VAF 138/381 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV52919201; called by muse, mutect2, varscan2
- OR2G3 | c.495A>T p.Q165H | Missense Mutation (SNP) | VAF 183/464 reads (39%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.982); catalogued as COSV60683240; called by muse, mutect2, varscan2
- OR2T12 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 69/676 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs753611689, COSV58776674; called by muse, mutect2, varscan2
- OR4C11 | c.779del p.P260Rfs*28 | Frame Shift Del (DEL) | VAF 42/168 reads (25%) | catalogued as rs764963140, COSV56352663, COSV56353360; called by mutect2, pindel
- OR4K14 | c.74A>T p.N25I | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779102209, COSV59293397, COSV59294244; called by muse, mutect2, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 56/163 reads (34%) | catalogued as rs748398423; called by mutect2, varscan2
- OR4Q3 | c.317G>C p.C106S | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59180395; called by muse, mutect2, varscan2
- OR51E1 | c.466del p.A156Lfs*3 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs1564877761; called by mutect2, pindel, varscan2
- OR5M1 | c.437C>A p.T146N | Missense Mutation (SNP) | VAF 86/221 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV101591585; called by muse, mutect2, varscan2
- OR8H3 | c.172A>G p.T58A | Missense Mutation (SNP) | VAF 52/390 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV100539095; called by muse, mutect2
- OR8I2 | c.119T>G p.L40W | Missense Mutation (SNP) | VAF 230/577 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs776616051, COSV56168135, COSV56170539; called by muse, mutect2, varscan2
- OSBPL2 | c.1380del p.D461Tfs*44 (on ENST00000313733 / NM_144498.4; = p.D449Tfs*44 on NM_014835.4) | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | catalogued as rs1298433831; called by mutect2, pindel, varscan2
- OSBPL5 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55143977; called by muse, mutect2, varscan2
- OTUD7A | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as rs746758362, COSV61043500; called by muse, mutect2, varscan2
- OXLD1 | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV61304002; called by muse, mutect2, varscan2
- PACS2 | c.254G>A p.S85N | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs201063885, COSV57657317; called by muse, mutect2, varscan2
- PACS2 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs781868356, COSV57657333, COSV99051049; called by muse, mutect2, varscan2
- PADI4 | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 111/254 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs143220365; called by muse, mutect2, varscan2
- PARD3B | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62531024; called by muse, mutect2, varscan2
- PARP14 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV72111803; called by muse, mutect2, varscan2
- PARP6 | c.1174A>G p.I392V | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.651); catalogued as COSV53005161; called by muse, mutect2, varscan2
- PAX2 | c.535A>G p.N179D | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.731); catalogued as COSV62293127; called by muse, mutect2, varscan2
- PAXBP1 | c.975+2T>C p.X325_splice | Splice Site (SNP) | VAF 30/271 reads (11%) | catalogued as COSV51612361; called by muse, mutect2, varscan2
- PBK | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV100107416; called by muse, mutect2
- PCDH12 | c.1172G>A p.C391Y | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51521751; called by muse, mutect2, varscan2
- PCDH18 | c.2741-1G>T p.X914_splice | Splice Site (SNP) | VAF 14/41 reads (34%) | catalogued as COSV61272257; called by muse, mutect2, varscan2
- PCDHA1 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as COSV65373324; called by muse, mutect2, varscan2
- PCDHAC2 | c.2197C>T p.R733C | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs782055086, COSV53843864; called by muse, mutect2, varscan2
- PCDHGA1 | c.2227G>A p.V743M | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.062); catalogued as rs762152002, COSV65299810; called by muse, mutect2, varscan2
- PCDHGA2 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs763969101, COSV53925705; called by muse, mutect2, varscan2
- PCSK7 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100309471; called by muse, mutect2, varscan2
- PDCD11 | c.5381G>A p.R1794H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779034592, COSV53297492; called by muse, mutect2, varscan2
- PDE4B | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs777377398, COSV58496286; called by muse, mutect2, varscan2
- PDE9A | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 122/346 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs376847913; called by muse, varscan2
- PDZD2 | c.3322del p.Q1108Sfs*17 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | catalogued as rs1212611383; called by mutect2, pindel, varscan2
- PEX5L | c.1373A>C p.K458T | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.892); catalogued as COSV55840118; called by muse, mutect2
- PHACTR1 | c.759del p.P254Qfs*59 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs749326031; called by mutect2, pindel, varscan2
- PHEX | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 211/785 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as CD005380, COSV65079140; called by muse, mutect2, varscan2
- PHKG1 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759747023, COSV51918975; called by muse, mutect2, varscan2
- PHLDB3 | c.733A>G p.S245G | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99415837; called by muse, mutect2, varscan2
- PIK3R1 | c.1891C>T p.R631* (on ENST00000521381 / NM_181523.3; = p.R361* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 74/215 reads (34%) | catalogued as rs761888083, COSV57134805; called by muse, mutect2, varscan2
- PKD1L2 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV100449800, COSV61419641; called by muse, mutect2, varscan2
- PKN2 | c.232del p.S78Vfs*5 | Frame Shift Del (DEL) | VAF 28/244 reads (11%) | catalogued as rs1335792632, COSV60133695; called by pindel, varscan2
- PLAU | c.1187G>T p.W396L | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65642101; called by muse, mutect2, varscan2
- PLEKHG6 | c.2151_2153del p.E718del | In Frame Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs960316144; called by pindel, varscan2
- PLPPR2 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as COSV52258486; called by muse, mutect2, varscan2
- PMS2 | c.1423G>A p.V475M | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs864622579, COSV56224245; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNPLA5 | c.693del p.S232Afs*4 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | catalogued as rs1218927828; called by mutect2, pindel, varscan2
- POLA1 | c.2053A>T p.T685S | Missense Mutation (SNP) | VAF 27/355 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as COSV100985680; called by muse, mutect2
- POLB | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs766919977, COSV55183675; called by muse, mutect2, varscan2
- POLD1 | c.1786G>A p.V596I | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs773180520, COSV70957476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 22/44 reads (50%) | catalogued as rs745933237; called by mutect2, pindel, varscan2
- PON2 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as COSV56003658; called by muse, mutect2, varscan2
- POU3F2 | c.859A>G p.T287A | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60409603; called by muse, mutect2, varscan2
- POU3F2 | c.1284del p.S429Vfs*60 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as COSV60408656, COSV60409574; called by mutect2, pindel, varscan2
- PPFIA4 | c.2785A>C p.S929R (on ENST00000447715; = p.S930R on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV55321731; called by muse, mutect2, varscan2
- PPP1R26 | c.2692del p.V898Sfs*56 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs1365223299; called by mutect2, pindel, varscan2
- PRDM9 | c.1424C>A p.A475D | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.585); catalogued as COSV57013456; called by muse, mutect2, varscan2
- PRDM9 | c.2077G>C p.V693L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as COSV57013462, COSV99690108; called by muse, varscan2
- PREX2 | c.3968T>C p.L1323P | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55799035; called by muse, mutect2, varscan2
- PRIM1 | c.623T>A p.I208N | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as COSV57718177; called by muse, mutect2, varscan2
- PRKACA | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as COSV100432173, COSV100432191; called by muse, varscan2
- PRKAG1 | c.9G>T p.T3= | Splice Region (SNP) | VAF 17/61 reads (28%) | catalogued as COSV56487202; called by muse, mutect2, varscan2
- PRKDC | c.9769A>T p.K3257* | Nonsense Mutation (SNP) | VAF 86/307 reads (28%) | catalogued as COSV58064018; called by muse, mutect2, varscan2
- PRORP | c.257del p.L86* | Frame Shift Del (DEL) | VAF 27/70 reads (39%) | catalogued as rs760446387; called by mutect2, varscan2
- PRUNE2 | c.196T>A p.F66I | Missense Mutation (SNP) | VAF 109/275 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65029636; called by muse, mutect2, varscan2
- PSD | c.593del p.G198Afs*19 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as COSV99194092; called by mutect2, pindel, varscan2
- PSORS1C2 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV52536655; called by muse, mutect2, varscan2
- PTK6 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV99420566; called by muse, mutect2, varscan2
- PTPRB | c.4380G>T p.K1460N | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99718301; called by muse, mutect2
- PTPRG | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.502); catalogued as rs1381071275; called by muse, mutect2
- PTPRJ | c.3373C>T p.R1125C | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs536396969, COSV69249788; called by muse, mutect2, varscan2
- PTPRK | c.3703A>G p.M1235V (on ENST00000368215 / NM_001291984.2; = p.M1236V on NM_002844.4) | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV63907392; called by muse, mutect2, varscan2
- PTPRS | c.1364G>A p.G455D | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53637588; called by muse, mutect2, varscan2
- PTPRT | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs757806313, COSV61962704; called by muse, mutect2, varscan2
- PYY | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100779011, COSV63972032; called by muse, mutect2, varscan2
- PZP | c.2933G>A p.C978Y | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1014590019, COSV54370604; called by muse, mutect2, varscan2
- QRICH2 | c.4348C>A p.L1450I | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53157899; called by muse, mutect2, varscan2
- R3HDM1 | c.3083A>G p.H1028R | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.921); catalogued as rs548074075, COSV51532915; called by muse, mutect2
- RALA | c.62G>C p.G21A | Missense Mutation (SNP) | VAF 94/272 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50050497; called by muse, mutect2, varscan2
- RALGAPB | c.2093C>A p.A698D | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.144); catalogued as COSV53444366; called by muse, mutect2, varscan2
- RAMP1 | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99614874; called by muse, mutect2, varscan2
- RARA | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV54197107; called by muse, mutect2, varscan2
- RBBP8NL | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1461516473, COSV99436828; called by muse, varscan2
- RBM47 | c.580C>A p.R194S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1560360999, COSV55929814; called by muse, varscan2
- REEP5 | c.380del p.P127Rfs*20 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | catalogued as COSV54842949; called by mutect2, pindel
- RFPL4B | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 82/280 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV71437809; called by muse, mutect2, varscan2
- RFX4 | c.724del p.V242Cfs*8 (on ENST00000392842 / NM_213594.3; = p.V148Cfs*8 on NM_032491.6) | Frame Shift Del (DEL) | VAF 38/221 reads (17%) | catalogued as COSV57581529; called by mutect2, pindel, varscan2
- RGS20 | c.498C>A p.S166R | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV99392391; called by muse, mutect2, varscan2
- RHOBTB1 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 89/261 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1484828070, COSV100558613; called by muse, mutect2, varscan2
- RIMS1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV53442254; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROBO3 | c.571del p.R191Afs*31 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | catalogued as rs756837590; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- ROPN1L | c.229G>T p.G77* | Nonsense Mutation (SNP) | VAF 33/102 reads (32%) | catalogued as COSV56875133; called by muse, mutect2, varscan2
- RPS6KA4 | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.063); catalogued as rs755881487, COSV53700910; called by muse, mutect2, varscan2
- RPUSD2 | c.1406A>G p.E469G | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100225241; called by muse, mutect2, varscan2
- RSKR | c.34A>G p.T12A | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.017); catalogued as COSV56384033; called by muse, mutect2
- RSRP1 | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99682685; called by muse, mutect2
- RTN1 | c.1520A>G p.E507G | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV99956327; called by muse, mutect2, varscan2
- RTN1 | c.902_903insA p.E302* | Frame Shift Ins (INS) | VAF 51/191 reads (27%) | catalogued as COSV50749499; called by mutect2, pindel, varscan2
- RYR3 | c.14054T>C p.V4685A (on ENST00000389232; = p.V4686A on NM_001036.6) | Missense Mutation (SNP) | VAF 148/426 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66808834; called by muse, mutect2, varscan2
- SAMD14 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs1276145651, COSV50305052; called by muse, mutect2, varscan2
- SAMD4A | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.448); catalogued as rs778052233, COSV51880189; called by muse, mutect2, varscan2
- SARS1 | c.392A>G p.N131S | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV52323297; called by muse, mutect2, varscan2
- SART3 | c.2768+1G>A p.X923_splice (on ENST00000228284; = p.X905_splice on NM_014706.4) | Splice Site (SNP) | VAF 58/159 reads (36%) | catalogued as rs1156458829, COSV57206894; called by muse, mutect2, varscan2
- SASS6 | c.670-1G>T p.X224_splice | Splice Site (SNP) | VAF 254/733 reads (35%) | catalogued as COSV54930465; called by muse, varscan2
- SATL1 | c.461T>C p.L154P (on ENST00000395409; = p.L341P on NM_001012980.2) | Missense Mutation (SNP) | VAF 105/1328 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.272); catalogued as COSV100261006, COSV60577858; called by muse, mutect2
- SBF2 | c.3395G>A p.R1132H | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs775391548, COSV56302958; called by muse, mutect2, varscan2
- SBK2 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.042); catalogued as rs367641925; called by muse, mutect2, varscan2
- SCAF11 | c.4303G>A p.A1435T | Missense Mutation (SNP) | VAF 208/519 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65479154; called by muse, mutect2, varscan2
- SCAF8 | c.3655A>G p.T1219A | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as COSV100914219; called by muse, mutect2, varscan2
- SCAI | c.692T>C p.V231A (on ENST00000336505 / NM_001144877.3; = p.V254A on NM_173690.5) | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs992069877, COSV60618045; called by muse, mutect2, varscan2
- SCYL3 | c.1655C>A p.P552H (on ENST00000367770; = p.P498H on NM_020423.7) | Missense Mutation (SNP) | VAF 93/262 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.312); catalogued as COSV53682764; called by muse, mutect2, varscan2
- SDAD1 | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs145814675; called by muse, mutect2, varscan2
- SDR9C7 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs141626978; called by muse, mutect2, varscan2
- SEMA3E | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 334/917 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57108979; called by muse, mutect2, varscan2
- SEMA6A | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs773059701, COSV57317900; called by muse, mutect2, varscan2
- SEMA6B | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.667); catalogued as COSV56704598; called by muse, mutect2, varscan2
- SF3B1 | c.3575T>C p.V1192A | Missense Mutation (SNP) | VAF 28/447 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV100134016; called by muse, mutect2
- SHC1 | c.92del p.P31Rfs*35 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | catalogued as rs752843778; called by mutect2, pindel, varscan2
- SHOX | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM021150, CM023452, COSV61861857, COSV61862377; called by muse, mutect2, varscan2
- SHROOM4 | c.3268G>T p.D1090Y | Missense Mutation (SNP) | VAF 81/289 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV56797366; called by muse, mutect2, varscan2
- SIAE | c.117G>T p.Q39H | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99704113; called by muse, mutect2, varscan2
- SIGLEC1 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.022); catalogued as rs745472020, COSV52460722; called by muse, mutect2, varscan2
- SLA | c.149G>A p.R50H (on ENST00000338087 / NM_001045556.3; = p.R90H on NM_006748.4) | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs140863357, COSV55094340; called by muse, mutect2, varscan2
- SLC10A2 | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV55361767; called by muse, mutect2, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | catalogued as rs767964038; called by mutect2, pindel, varscan2
- SLC20A2 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60607117; called by muse, mutect2, varscan2
- SLC22A16 | c.1643G>T p.S548I | Missense Mutation (SNP) | VAF 97/303 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV57934792; called by muse, mutect2, varscan2
- SLC26A1 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs763566253, COSV99926228; called by muse, varscan2
- SLC2A14 | c.526G>A p.G176S | Missense Mutation (SNP) | VAF 133/530 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61588643; called by muse, mutect2, varscan2
- SLC35G2 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 129/354 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.185); catalogued as COSV67588333, COSV67589045; called by muse, mutect2, varscan2
- SLC39A13 | c.1007T>C p.V336A (on ENST00000362021 / NM_001128225.3; = p.V329A on NM_152264.4) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100099681; called by muse, mutect2
- SLC4A11 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs1298347142, CM081819, COSV66262847; called by muse, mutect2, varscan2
- SLC4A2 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV59659360; called by muse, mutect2, varscan2
- SLC4A3 | c.1702T>C p.Y568H | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56097671; called by muse, mutect2, varscan2
- SLC51A | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as rs1197255768, COSV99580365; called by muse, mutect2, varscan2
- SLC7A5 | c.1480G>A p.V494I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs200265403; called by muse, mutect2, varscan2
- SLC8B1 | c.239A>G p.Y80C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1417650088, COSV52530659; called by muse, mutect2, varscan2
- SMC1A | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 154/506 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV59131948; called by muse, mutect2, varscan2
- SMG7 | c.3278C>T p.A1093V | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV61634344; called by muse, mutect2, varscan2
- SND1 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.985); catalogued as rs993188344, COSV61249356; called by muse, mutect2, varscan2
- SNRPB2 | c.25A>T p.I9F | Missense Mutation (SNP) | VAF 202/582 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV55719827; called by muse, mutect2, varscan2
- SORBS2 | c.2132del p.N711Ifs*65 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs754977280; called by mutect2, varscan2
- SORCS1 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.05); catalogued as rs754071767, COSV53874846; called by muse, mutect2, varscan2
- SP4 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.292); catalogued as rs1305715394, COSV56021999; called by muse, varscan2
- SPAG6 | c.1234A>G p.T412A | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as COSV100510020, COSV57624083; called by muse, varscan2
- SPATC1 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as rs782379736, COSV101085015, COSV66300143; called by muse, mutect2, varscan2
- SPEG | c.9587G>A p.R3196Q | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs770996931, COSV56663366; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPIN1 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 90/248 reads (36%) | catalogued as rs11142308, COSV65501199; called by muse, varscan2
- SPIN2A | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 183/894 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.429); catalogued as rs368936498, COSV100888065; called by muse, mutect2, varscan2
- SPTA1 | c.2820G>T p.K940N | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759064678, COSV63756277, COSV63759629; called by muse, mutect2, varscan2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | catalogued as rs748467821; called by mutect2, varscan2
- SRCAP | c.7725_7727del p.S2576del | In Frame Del (DEL) | VAF 20/74 reads (27%) | catalogued as rs797046007; called by pindel, varscan2
- SRCAP | c.8258G>A p.R2753Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV52681302; called by muse, mutect2, varscan2
- SSMEM1 | c.509A>G p.H170R | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV52833721; called by muse, mutect2
- ST14 | c.2224G>A p.G742S | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332165467, COSV53837052; called by muse, mutect2, varscan2
- ST3GAL3 | c.1123C>T p.R375W (on ENST00000361392 / NM_174964.4; = p.R360W on NM_006279.5) | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs546025340, COSV99495773; called by muse, varscan2
- ST3GAL3 | c.1144G>A p.V382I (on ENST00000361392 / NM_174964.4; = p.V367I on NM_006279.5) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.332); catalogued as rs369157620; ClinVar: uncertain significance; called by muse, varscan2
- ST6GAL2 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 37/88 reads (42%) | PolyPhen benign (0.362); catalogued as rs757962368, COSV62418156; called by muse, mutect2, varscan2
- STAU2 | c.1091dup p.N364Kfs*13 (on ENST00000524300 / NM_001164380.2; = p.N332Kfs*13 on NM_014393.2) | Frame Shift Ins (INS) | VAF 95/515 reads (18%) | catalogued as rs746501298; called by mutect2, varscan2
- STAU2 | c.131T>C p.L44P (on ENST00000524300 / NM_001164380.2; = p.L12P on NM_014393.2) | Missense Mutation (SNP) | VAF 74/278 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62479804; called by muse, mutect2
- SYT1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs144005237; called by muse, mutect2, varscan2
- SYTL5 | c.1646T>C p.V549A | Missense Mutation (SNP) | VAF 94/605 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV99937471; called by muse, mutect2, varscan2
- SZT2 | c.9965A>G p.Q3322R (on ENST00000634258 / NM_001365999.1; = p.Q3265R on NM_015284.4) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.558); catalogued as COSV65095414; called by muse, mutect2, varscan2
- TAF5 | c.1268C>A p.P423H | Missense Mutation (SNP) | VAF 141/415 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV60858076; called by muse, mutect2, varscan2
- TANC1 | c.2416C>T p.R806* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV55092644; called by muse, mutect2, varscan2
- TAOK1 | c.1925A>G p.Q642R | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.989); catalogued as COSV55598891; called by muse, mutect2
- TARBP2 | c.769C>T p.R257* (on ENST00000266987 / NM_134323.2; = p.R236* on NM_004178.4) | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as rs758198296, COSV99908598; called by muse, mutect2, varscan2
- TBC1D5 | c.1576C>T p.Q526* | Nonsense Mutation (SNP) | VAF 94/313 reads (30%) | catalogued as rs1443299478, COSV53771250; called by muse, mutect2, varscan2
- TBC1D9 | c.3560C>T p.T1187M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs770941144, COSV71308963; called by muse, mutect2, varscan2
- TCFL5 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs1459032732, COSV53895685; called by muse, mutect2
- TENM1 | c.4001C>T p.A1334V | Missense Mutation (SNP) | VAF 169/359 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV64443583; called by muse, mutect2, varscan2
- TENM3 | c.3068C>G p.T1023S | Missense Mutation (SNP) | VAF 75/188 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV69319546; called by muse, mutect2, varscan2
- TENM3 | c.6016C>T p.R2006C | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1242840827, COSV69313466; called by muse, mutect2, varscan2
- TENT4B | c.1246C>T p.R416* (on ENST00000561678 / NM_001365323.2; = p.R401* on NM_001040284.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 117/318 reads (37%) | catalogued as COSV62549135; called by muse, mutect2, varscan2
- TEX11 | c.2138A>C p.E713A (on ENST00000344304; = p.E698A on NM_031276.3) | Missense Mutation (SNP) | VAF 110/492 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV60239420; called by muse, mutect2
- TFB1M | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 120/325 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs368405074; called by muse, mutect2, varscan2
- TFE3 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1411173446, COSV59945949; called by muse, mutect2, varscan2
- TFPI | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 81/210 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV51905843; called by muse, mutect2, varscan2
- TGFB1 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1274564517, COSV55726086; called by muse, mutect2, varscan2
- TGM6 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs201204278, COSV52480897; called by muse, mutect2, varscan2
- THEM5 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs558957960, COSV64312800; called by muse, mutect2, varscan2
- TLE3 | c.594G>A p.A198= | Splice Region (SNP) | VAF 20/90 reads (22%) | catalogued as COSV100450519, COSV58174590; called by muse, mutect2, varscan2
- TLR10 | c.1316G>T p.R439M | Missense Mutation (SNP) | VAF 52/314 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV100457881; called by muse, mutect2, varscan2
- TMEM131L | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.842); catalogued as rs201534569, COSV53642719; called by muse, mutect2, varscan2
- TMEM63B | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV52482501; called by muse, mutect2, varscan2
- TMTC2 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs573420920, COSV58268300; called by muse, mutect2, varscan2
- TNFRSF21 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1342962253, COSV57284169; called by muse, mutect2, varscan2
- TNRC6C | c.3902C>T p.T1301M | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56953054; called by muse, mutect2, varscan2
- TONSL | c.3488G>A p.R1163H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs782299928, COSV68049479; called by muse, mutect2, varscan2
- TPH2 | c.925C>A p.L309I | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.626); catalogued as COSV61591452, COSV61594396; called by muse, mutect2, varscan2
- TPTE | c.1510G>A p.E504K (on ENST00000618007 / NM_199261.4; = p.E486K on NM_199259.4) | Missense Mutation (SNP) | VAF 155/1129 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as rs775113189; called by muse, mutect2, varscan2
- TRABD2A | c.1309G>A p.D437N (on ENST00000409520 / NM_001277053.2; = p.D388N on NM_001080824.3) | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs755189333, COSV52883687; called by muse, mutect2, varscan2
- TRAF7 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs751318317, COSV58218349; called by muse, mutect2, varscan2
- TRAPPC8 | c.1430C>A p.P477H | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV51977610; called by muse, mutect2, varscan2
- TRHR | c.511T>C p.Y171H | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV61236580; called by muse, mutect2, varscan2
- TRIB1 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1257256547, COSV61335626; called by muse, mutect2, varscan2
- TRIM3 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs373824947, COSV61985668; called by muse, mutect2, varscan2
- TRIP6 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 93/205 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.36); catalogued as COSV51937134; called by muse, mutect2, varscan2
- TRMT9B | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs758134647, COSV71600823; called by muse, mutect2, varscan2
- TRPV5 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs199871524, COSV54685631; called by muse, mutect2, varscan2
- TSC2 | c.2749C>T p.R917W | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781587135, COSV54780192; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSNARE1 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.789); catalogued as rs199897318; called by mutect2, varscan2
- TTC21A | c.2259G>T p.E753D | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.415); catalogued as COSV57185070, COSV57189517; called by muse, mutect2, varscan2
- TTC5 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51872301; called by muse, mutect2, varscan2
- TUBG1 | c.1263G>T p.M421I | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99258825; called by muse, mutect2, varscan2
- TWF1 | c.301T>C p.Y101H | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV57301984; called by muse, mutect2, varscan2
- TXNDC16 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 129/358 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.705); catalogued as COSV55987610; called by muse, mutect2, varscan2
- UBN1 | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52173087; called by muse, mutect2, varscan2
- UGGT2 | c.3388-2A>G p.X1130_splice | Splice Site (SNP) | VAF 28/256 reads (11%) | catalogued as COSV65079553; called by muse, mutect2
- UGT3A2 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 130/339 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as COSV56933578; called by muse, mutect2, varscan2
- ULK2 | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100860923; called by muse, mutect2, varscan2
- UNC13A | c.3496G>A p.G1166S | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV53210596; called by muse, mutect2, varscan2
- UTP4 | c.1756A>G p.I586V | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as rs1567383447, COSV58734652; called by muse, mutect2
- VPS13B | c.5389G>T p.G1797C | Missense Mutation (SNP) | VAF 180/358 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62157296, COSV62159947; called by muse, mutect2, varscan2
- VPS28 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782001806, COSV52873622; called by muse, mutect2, varscan2
- VPS53 | c.1882G>A p.V628M (on ENST00000571805 / NM_001366253.2; = p.V599M on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs771258247, COSV52137884; called by muse, mutect2, varscan2
- WDR59 | c.2515C>T p.R839* | Nonsense Mutation (SNP) | VAF 51/157 reads (32%) | catalogued as rs200814192, COSV50940094; called by muse, mutect2, varscan2
- WDR62 | c.2146G>T p.E716* | Nonsense Mutation (SNP) | VAF 70/190 reads (37%) | catalogued as COSV99543998; called by muse, varscan2
- WDR62 | c.2318G>A p.R773Q | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs762688861, COSV99544000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR7 | c.2048T>C p.L683P | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.347); catalogued as COSV54363330; called by muse, mutect2, varscan2
- WHRN | c.1357A>G p.S453G | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV99470455; called by muse, mutect2
- WWC3 | c.1126C>A p.R376S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66504490, COSV66507442; called by muse, mutect2, varscan2
- XPR1 | c.523T>A p.W175R | Missense Mutation (SNP) | VAF 36/395 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62560684; called by muse, mutect2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- YBX1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as rs1292066943, COSV58440229; called by muse, mutect2, varscan2
- YLPM1 | c.2445del p.P816Qfs*13 | Frame Shift Del (DEL) | VAF 48/148 reads (32%) | catalogued as COSV99459136, COSV99461629; called by mutect2, pindel, varscan2
- YTHDF2 | c.1408G>A p.V470M | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.902); catalogued as rs775516240, COSV65724202; called by muse, mutect2, varscan2
- ZBED9 | c.61dup p.E21Gfs*8 | Frame Shift Ins (INS) | VAF 67/263 reads (25%) | catalogued as rs1251431620; called by mutect2, pindel, varscan2
- ZBTB38 | c.3023G>A p.R1008Q | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV58544289; called by muse, mutect2, varscan2
- ZBTB7C | c.394del p.D132Tfs*90 | Frame Shift Del (DEL) | VAF 78/266 reads (29%) | catalogued as COSV59691020; called by mutect2, pindel, varscan2
- ZFC3H1 | c.5298G>T p.E1766D | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV101110632; called by muse, mutect2, varscan2
- ZFP36 | c.736del p.L246Wfs*126 (on ENST00000594442; = p.L240Wfs*126 on NM_003407.5) | Frame Shift Del (DEL) | VAF 43/136 reads (32%) | catalogued as rs1568383502; called by mutect2, pindel, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | catalogued as rs753611080; called by mutect2, varscan2
- ZNF107 | c.2087A>G p.E696G | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1279580917, COSV100788446; called by muse, mutect2, varscan2
- ZNF277 | c.738del p.K246Nfs*87 | Frame Shift Del (DEL) | VAF 29/215 reads (13%) | catalogued as rs749826488; called by mutect2, pindel, varscan2
- ZNF282 | c.1907G>T p.G636V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV50484110; called by muse, mutect2, varscan2
- ZNF324 | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs1039107467; called by muse, varscan2
- ZNF35 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as rs181680635, COSV56077489; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 30/68 reads (44%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF37A | c.398T>C p.L133P | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100697405; called by muse, mutect2
- ZNF385B | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.102); catalogued as rs544716600, COSV101343136, COSV69800485; called by muse, mutect2, varscan2
- ZNF385D | c.436del p.T146Qfs*24 | Frame Shift Del (DEL) | VAF 95/642 reads (15%) | catalogued as COSV55746833; called by mutect2, pindel, varscan2
- ZNF460 | c.230A>G p.Q77R | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs766954895, COSV64416479; called by muse, mutect2
- ZNF471 | c.1749C>A p.S583R | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV57293645; called by muse, mutect2, varscan2
- ZNF532 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.387); catalogued as rs772801429, COSV60172528; called by muse, mutect2, varscan2
- ZNF57 | c.732A>T p.R244S | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV60984747; called by muse, mutect2, varscan2
- ZNF644 | c.2996T>C p.V999A | Missense Mutation (SNP) | VAF 100/742 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as COSV100494605; called by muse, varscan2
- ZNF780B | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV55468371; called by muse, mutect2, varscan2
- ZSCAN31 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs768839187, COSV60180747; called by muse, mutect2, varscan2
- ZXDB | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 66/323 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100885994; called by muse, mutect2, varscan2
- ZYX | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV59556396; called by muse, mutect2, varscan2
- ABCC10 | c.1747del p.Q583Rfs*41 (on ENST00000372530 / NM_001198934.2; = p.Q540Rfs*11 on NM_033450.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 35/120 reads (29%) | called by mutect2, pindel, varscan2
- ADAM18 | c.1676del p.N559Mfs*23 | Frame Shift Del (DEL) | VAF 77/310 reads (25%) | called by mutect2, pindel, varscan2
- ADRM1 | c.*1_*4dup | Frame Shift Ins (INS) | VAF 37/175 reads (21%) | called by mutect2, pindel, varscan2
- APOB | c.13622del p.K4541Sfs*8 | Frame Shift Del (DEL) | VAF 176/611 reads (29%) | called by mutect2, pindel, varscan2
- ARAP3 | c.2287A>G p.R763G | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- ARF5 | c.121del p.E41Rfs*9 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by mutect2, pindel, varscan2
- ARHGAP22 | c.2044del p.S682Rfs*3 | Frame Shift Del (DEL) | VAF 95/300 reads (32%) | called by mutect2, pindel
- ASCC2 | c.702dup p.S235Qfs*2 | Frame Shift Ins (INS) | VAF 19/86 reads (22%) | called by pindel, varscan2
- C2CD3 | c.1429dup p.I477Nfs*12 | Frame Shift Ins (INS) | VAF 96/308 reads (31%) | called by mutect2, varscan2
- C4BPB | c.755_757del p.L252del | In Frame Del (DEL) | VAF 84/252 reads (33%) | called by pindel, varscan2
- CAD | c.2706_2707del p.Q902Hfs*2 | Frame Shift Del (DEL) | VAF 51/141 reads (36%) | called by mutect2, pindel, varscan2
- CDKL2 | c.1104del p.G369Afs*20 | Frame Shift Del (DEL) | VAF 109/366 reads (30%) | called by mutect2, pindel, varscan2
- CEP162 | c.3542del p.N1181Mfs*3 | Frame Shift Del (DEL) | VAF 34/196 reads (17%) | called by mutect2, varscan2
- CFH | c.469dup p.I157Nfs*4 | Frame Shift Ins (INS) | VAF 68/242 reads (28%) | called by mutect2, pindel, varscan2
- CLASRP | c.284del p.P95Lfs*81 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | called by mutect2, pindel, varscan2
- CRB1 | c.4199del p.P1400Lfs*6 | Frame Shift Del (DEL) | VAF 35/111 reads (32%) | called by mutect2, pindel, varscan2
- CTIF | c.245del p.P82Hfs*77 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- CYP4V2 | c.1412del p.K471Sfs*4 | Frame Shift Del (DEL) | VAF 46/173 reads (27%) | called by mutect2, pindel, varscan2
- DDX6 | c.231del p.K77Nfs*7 | Frame Shift Del (DEL) | VAF 72/216 reads (33%) | called by mutect2, pindel, varscan2
- DHX57 | c.887del p.N296Mfs*39 | Frame Shift Del (DEL) | VAF 82/258 reads (32%) | called by mutect2, pindel, varscan2
- DNAJC1 | c.1258dup p.V420Gfs*13 | Frame Shift Ins (INS) | VAF 21/175 reads (12%) | called by mutect2, pindel, varscan2
- DOCK11 | c.848dup p.E284Gfs*9 | Frame Shift Ins (INS) | VAF 115/536 reads (21%) | called by mutect2, varscan2
- E2F2 | c.106dup p.Q36Pfs*66 | Frame Shift Ins (INS) | VAF 52/136 reads (38%) | called by mutect2, pindel, varscan2
- EBF1 | c.1509del p.T504Pfs*14 | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | called by mutect2, pindel, varscan2
- EEF2 | c.721del p.E241Rfs*13 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- EIF3E | c.41del p.L14Wfs*5 | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | called by mutect2, pindel, varscan2
- ENDOV | c.270dup p.Y91Lfs*150 | Frame Shift Ins (INS) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- EOMES | c.1868del p.P623Lfs*6 | Frame Shift Del (DEL) | VAF 44/297 reads (15%) | called by mutect2, pindel, varscan2
- EPS15 | c.2365del p.R789Dfs*14 | Frame Shift Del (DEL) | VAF 50/169 reads (30%) | called by mutect2, pindel, varscan2
- EVC2 | c.1991del p.K664Rfs*8 | Frame Shift Del (DEL) | VAF 204/732 reads (28%) | called by pindel, varscan2
- FBXL2 | c.349del p.I117Sfs*16 | Frame Shift Del (DEL) | VAF 79/264 reads (30%) | called by mutect2, pindel, varscan2
- FCGBP | c.12079T>C p.C4027R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FN1 | c.5140del p.L1714* | Frame Shift Del (DEL) | VAF 28/156 reads (18%) | called by mutect2, pindel, varscan2
- FSIP2 | c.18963del p.V6322* | Frame Shift Del (DEL) | VAF 84/246 reads (34%) | called by mutect2, pindel, varscan2
- FXR1 | c.371dup p.N124Kfs*5 | Frame Shift Ins (INS) | VAF 47/160 reads (29%) | called by mutect2, varscan2
- HOXD8 | c.369del p.C124Afs*53 | Frame Shift Del (DEL) | VAF 10/16 reads (63%) | called by mutect2, varscan2
- HP1BP3 | c.1159del p.T387Pfs*86 | Frame Shift Del (DEL) | VAF 141/446 reads (32%) | called by mutect2, pindel, varscan2
- HSFX1 | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 76/282 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); called by mutect2, varscan2
- INO80 | c.3952del p.R1318Gfs*6 | Frame Shift Del (DEL) | VAF 23/163 reads (14%) | called by mutect2, pindel, varscan2
- IQGAP2 | c.2641del p.T881Hfs*2 | Frame Shift Del (DEL) | VAF 120/398 reads (30%) | called by mutect2, pindel, varscan2
- IQGAP3 | c.3613del p.Q1205Sfs*31 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- KCNN2 | c.1262del p.N421Mfs*12 (on ENST00000264773; = p.N633Mfs*12 on NM_021614.4) | Frame Shift Del (DEL) | VAF 91/297 reads (31%) | called by mutect2, varscan2
- KDM5A | c.3596_3597del p.K1199Rfs*7 | Frame Shift Del (DEL) | VAF 49/214 reads (23%) | called by pindel, varscan2*
- KIF13A | c.956del p.G319Afs*7 | Frame Shift Del (DEL) | VAF 106/339 reads (31%) | called by mutect2, pindel, varscan2
- LCP2 | c.1360dup p.T454Nfs*15 | Frame Shift Ins (INS) | VAF 170/520 reads (33%) | called by mutect2, varscan2
- LSM14A | c.821dup p.H275Sfs*19 | Frame Shift Ins (INS) | VAF 27/157 reads (17%) | called by mutect2, pindel, varscan2
- MAP3K9 | c.1850dup p.Q618Sfs*4 | Frame Shift Ins (INS) | VAF 8/74 reads (11%) | called by mutect2, pindel
- MARF1 | c.4676del p.N1559Mfs*3 | Frame Shift Del (DEL) | VAF 60/387 reads (16%) | called by mutect2, varscan2
- MASTL | c.1173del p.K391Nfs*12 | Frame Shift Del (DEL) | VAF 31/143 reads (22%) | called by mutect2, pindel, varscan2
- MCM4 | c.1885del p.T629Qfs*18 | Frame Shift Del (DEL) | VAF 46/198 reads (23%) | called by mutect2, varscan2
- MED13 | c.2226_2228del p.E742del | In Frame Del (DEL) | VAF 108/348 reads (31%) | called by pindel, varscan2
- MTHFD1L | c.1759del p.I587* | Frame Shift Del (DEL) | VAF 16/165 reads (10%) | called by mutect2, pindel
- MUC2 | c.372del p.L126Cfs*104 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- MUC2 | c.2540G>A p.G847E | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- MYH1 | c.923_925del p.T308del | In Frame Del (DEL) | VAF 210/748 reads (28%) | called by pindel, varscan2
- NELFE | c.18del p.G7Dfs*2 | Frame Shift Del (DEL) | VAF 72/213 reads (34%) | called by mutect2, pindel
- NFE2L3 | c.1959dup p.G654Rfs*2 | Frame Shift Ins (INS) | VAF 47/292 reads (16%) | called by mutect2, pindel, varscan2
- NLRP8 | c.665del p.K222Rfs*2 | Frame Shift Del (DEL) | VAF 18/166 reads (11%) | called by mutect2, pindel, varscan2
- NME8 | c.15dup p.R6Tfs*11 | Frame Shift Ins (INS) | VAF 86/290 reads (30%) | called by pindel, varscan2
- NUFIP1 | c.240dup p.F81Lfs*20 | Frame Shift Ins (INS) | VAF 20/67 reads (30%) | called by mutect2, pindel, varscan2
- OR2J3 | c.39dup p.Y14Vfs*9 | Frame Shift Ins (INS) | VAF 124/445 reads (28%) | called by mutect2, pindel, varscan2
- PAX8 | c.989del p.L330Wfs*96 | Frame Shift Del (DEL) | VAF 29/109 reads (27%) | called by mutect2, pindel, varscan2
- PCDHB7 | c.1617del p.A540Rfs*2 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | called by mutect2, pindel
- PCLO | c.5737del p.S1913Vfs*9 | Frame Shift Del (DEL) | VAF 124/458 reads (27%) | called by mutect2, pindel, varscan2
- PCM1 | c.5975del p.N1992Tfs*15 | Frame Shift Del (DEL) | VAF 133/584 reads (23%) | called by mutect2, pindel, varscan2
- PHF20L1 | c.965del p.N322Mfs*42 | Frame Shift Del (DEL) | VAF 72/252 reads (29%) | called by mutect2, varscan2
- PHRF1 | c.2813del p.P938Qfs*23 (on ENST00000264555 / NM_001286581.2; = p.P937Qfs*23 on NM_020901.4) | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- PIK3R5 | c.1798dup p.W600Lfs*7 | Frame Shift Ins (INS) | VAF 27/181 reads (15%) | called by mutect2, pindel, varscan2
- PNISR | c.1491dup p.E498Rfs*3 | Frame Shift Ins (INS) | VAF 102/338 reads (30%) | called by mutect2, varscan2
- PNMA3 | c.375dup p.S126Vfs*56 | Frame Shift Ins (INS) | VAF 21/97 reads (22%) | called by mutect2, pindel, varscan2
- PRAMEF7 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 133/290 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PRKDC | c.12110del p.N4037Ifs*15 | Frame Shift Del (DEL) | VAF 55/391 reads (14%) | called by mutect2, pindel, varscan2
- PRKDC | c.8110del p.R2704Gfs*13 | Frame Shift Del (DEL) | VAF 76/285 reads (27%) | called by mutect2, varscan2
- PRPF4B | c.3019dup p.I1007Nfs*13 | Frame Shift Ins (INS) | VAF 128/380 reads (34%) | called by mutect2, varscan2
- PRRG3 | c.634dup p.Y212Lfs*3 | Frame Shift Ins (INS) | VAF 20/98 reads (20%) | called by pindel, varscan2
- PSMD5 | c.831dup p.G278Wfs*8 | Frame Shift Ins (INS) | VAF 14/77 reads (18%) | called by mutect2, pindel, varscan2
- RAD51AP2 | c.946del p.T316Lfs*2 | Frame Shift Del (DEL) | VAF 26/295 reads (9%) | called by mutect2, pindel
- RANBP2 | c.8209del p.C2737Vfs*35 | Frame Shift Del (DEL) | VAF 38/232 reads (16%) | called by mutect2, varscan2
- RAPGEF6 | c.2495del p.N832Ifs*17 | Frame Shift Del (DEL) | VAF 68/213 reads (32%) | called by mutect2, pindel, varscan2
- RCVRN | c.576del p.V193* | Frame Shift Del (DEL) | VAF 150/444 reads (34%) | called by mutect2, varscan2
- RER1 | c.464T>C p.I155T | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- REV3L | c.8049del p.G2684Vfs*11 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by mutect2, pindel, varscan2
- RGS22 | c.2742del p.K914Nfs*18 | Frame Shift Del (DEL) | VAF 60/454 reads (13%) | called by mutect2, pindel, varscan2
- RGS4 | c.338del p.K113Rfs*15 | Frame Shift Del (DEL) | VAF 102/327 reads (31%) | called by mutect2, pindel, varscan2
- RNF103 | c.609del p.F203Lfs*4 | Frame Shift Del (DEL) | VAF 38/300 reads (13%) | called by mutect2, pindel, varscan2
- RPL30 | c.299-3del | Splice Region (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- RTL3 | c.1210del p.S404Vfs*101 | Frame Shift Del (DEL) | VAF 73/315 reads (23%) | called by mutect2, pindel, varscan2
- SAMD9 | c.1014dup p.F339Ifs*12 | Frame Shift Ins (INS) | VAF 217/744 reads (29%) | called by mutect2, pindel, varscan2
- SCAF11 | c.810dup p.P271Sfs*56 | Frame Shift Ins (INS) | VAF 134/503 reads (27%) | called by mutect2, pindel, varscan2
- SCAPER | c.2835dup p.E946Rfs*19 | Frame Shift Ins (INS) | VAF 10/83 reads (12%) | called by mutect2, pindel, varscan2
- SHBG | c.1084del p.C362Afs*2 | Frame Shift Del (DEL) | VAF 19/143 reads (13%) | called by mutect2, pindel, varscan2
- SLC38A1 | c.407del p.K136Sfs*14 | Frame Shift Del (DEL) | VAF 31/114 reads (27%) | called by mutect2, pindel, varscan2
- SLC7A4 | c.1291del p.L431* | Frame Shift Del (DEL) | VAF 25/73 reads (34%) | called by mutect2, pindel, varscan2
- SLITRK2 | c.799del p.S267Vfs*23 | Frame Shift Del (DEL) | VAF 20/79 reads (25%) | called by mutect2, pindel, varscan2
- SMARCD2 | c.1294_1296del p.E432del | In Frame Del (DEL) | VAF 38/107 reads (36%) | called by pindel, varscan2
- TBC1D12 | c.2250del p.K750Nfs*9 | Frame Shift Del (DEL) | VAF 45/160 reads (28%) | called by mutect2, pindel, varscan2
- TET3 | c.4429del p.A1477Pfs*54 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- THSD7B | c.4563del p.A1522Lfs*3 (on ENST00000272643; = p.A1520Lfs*3 on NM_001316349.2) | Frame Shift Del (DEL) | VAF 87/310 reads (28%) | called by mutect2, pindel, varscan2
- TMC8 | c.1480dup p.L494Pfs*7 | Frame Shift Ins (INS) | VAF 39/126 reads (31%) | called by mutect2, pindel, varscan2
- TMEM92 | c.413del p.P138Lfs*86 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | called by mutect2, varscan2
- TOP2A | c.4594del p.*1532Kfs*3 | Frame Shift Del (DEL) | VAF 49/145 reads (34%) | called by mutect2, pindel, varscan2
- TOP2A | c.3613del p.T1205Hfs*19 | Frame Shift Del (DEL) | VAF 78/241 reads (32%) | called by mutect2, varscan2
- TTK | c.575del p.K192Sfs*18 | Frame Shift Del (DEL) | VAF 52/150 reads (35%) | called by mutect2, varscan2
- UBR5 | c.3060dup p.I1021Hfs*5 | Frame Shift Ins (INS) | VAF 25/125 reads (20%) | called by mutect2, pindel, varscan2
- UPF3A | c.393dup p.D132* | Frame Shift Ins (INS) | VAF 151/524 reads (29%) | called by mutect2, pindel
- USP7 | c.1594A>G p.T532A | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.067); called by muse, mutect2
- YTHDF2 | c.404dup p.N136Kfs*2 | Frame Shift Ins (INS) | VAF 64/212 reads (30%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 53/99 reads (54%) | called by mutect2, pindel, varscan2
- ZBTB7C | c.960del p.P321Lfs*18 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- ZNF451 | c.660del p.K220Nfs*85 | Frame Shift Del (DEL) | VAF 54/193 reads (28%) | called by mutect2, pindel, varscan2
- A2M | c.2619C>T p.S873= | Silent (SNP) | VAF 104/423 reads (25%) | catalogued as rs767057851, COSV59383584; called by muse, mutect2, varscan2
225 further variants in this file (0 protein-altering or splice-affecting, 208 silent, 17 other) are not listed here.
